Somatic mutation profile of tumor specimen TCGA-64-1676-01A (aliquot TCGA-64-1676-01A-01W-0928-08) from TCGA case TCGA-64-1676, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 58.7 years (21,428 days).
Specimen TCGA-64-1676-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a07cd798-794d-4e32-8afb-1dcf7a436a83.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-64-1676-10A (Blood Derived Normal), aliquot TCGA-64-1676-10A-01D-0969-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87f38292-1424-4c71-a878-6410ff23e88f

The open-access MAF lists 619 somatic variants for this specimen: 475 protein-altering or splice-affecting, 134 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 414, Silent 134, Nonsense Mutation 33, Splice Site 13, Frame Shift Del 9, Intron 4, Frame Shift Ins 3, 5'Flank 3, Splice Region 2, RNA 2, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GBE1 | c.1693C>T p.R565W | Missense Mutation (SNP) | VAF 56/103 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs552094593, COSV70098920; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- LDLRAP1 | c.603dup p.S202Lfs*19 | Frame Shift Ins (INS) | VAF 5/41 reads (12%) | catalogued as rs781585299; ClinVar: pathogenic; called by pindel, varscan2
- MAP2K1 | c.361T>A p.C121S | Missense Mutation (SNP) | VAF 65/212 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1057519856, COSV100199074, COSV61068761; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.3928G>T p.G1310W | Missense Mutation (SNP) | VAF 94/242 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59385820; called by muse, mutect2, varscan2
- ABCA10 | c.1289G>T p.G430V | Missense Mutation (SNP) | VAF 31/217 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52221469; called by muse, mutect2, varscan2
- ABCA4 | c.4237C>A p.Q1413K | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.784); catalogued as COSV64673194; called by muse, mutect2, varscan2
- ABCB9 | c.842G>T p.R281L | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.124); catalogued as COSV54891518; called by muse, mutect2, varscan2
- AC006059.2 | c.288G>T p.K96N | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.139); catalogued as COSV59606722; called by muse, mutect2, varscan2
- ACAN | c.4370T>C p.L1457P | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.054); catalogued as COSV61359738; called by muse, mutect2, varscan2
- ACP5 | c.350T>A p.V117D | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54536139; called by muse, mutect2, varscan2
- ACTN2 | c.1325G>T p.R442L | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV63974666; called by muse, mutect2, varscan2
- ADAMTS1 | c.2812C>T p.H938Y | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.97); PolyPhen benign (0.012); catalogued as COSV53170087; called by muse, mutect2, varscan2
- ADAMTS12 | c.1507G>T p.V503L | Missense Mutation (SNP) | VAF 149/527 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV61262006; called by muse, mutect2, varscan2
- ADAMTS17 | c.1615C>A p.P539T | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV51472348; called by muse, mutect2, varscan2
- ADAMTS19 | c.1568G>T p.G523V | Missense Mutation (SNP) | VAF 287/730 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV50745026; called by muse, mutect2, varscan2
- ADAMTS20 | c.456G>T p.T152= | Splice Region (SNP) | VAF 184/443 reads (42%) | catalogued as COSV67129970, COSV67130694; called by muse, mutect2, varscan2
- ADAMTSL1 | c.784A>C p.K262Q | Missense Mutation (SNP) | VAF 45/220 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV52814900; called by muse, mutect2, varscan2
- ADCY8 | c.1225C>G p.R409G | Missense Mutation (SNP) | VAF 57/232 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV53903757, COSV99654082; called by muse, mutect2, varscan2
- ADCY9 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV53574676; called by muse, mutect2, varscan2
- ADGRB3 | c.2322G>T p.L774F | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV65393281, COSV65393816; called by muse, mutect2, varscan2
- ADGRF2 | c.448C>A p.L150I (on ENST00000296862 / NM_001368115.2; = p.L82I on NM_153839.7) | Missense Mutation (SNP) | VAF 21/203 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV57288082; called by muse, mutect2, varscan2
- ADGRG4 | c.2257G>T p.E753* | Nonsense Mutation (SNP) | VAF 482/701 reads (69%) | catalogued as COSV54955096, COSV54958897; called by muse, mutect2, varscan2
- ADH1B | c.577G>T p.G193C | Missense Mutation (SNP) | VAF 167/529 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59296199; called by muse, mutect2, varscan2
- ADRA1A | c.829G>C p.V277L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52362801; called by mutect2, varscan2
- AGBL1 | c.432G>T p.M144I | Missense Mutation (SNP) | VAF 118/356 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.138); catalogued as COSV69798396; called by muse, mutect2, varscan2
- AGMO | c.804T>A p.F268L | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV61111559; called by muse, mutect2, varscan2
- AGO1 | c.1948C>T p.Q650* | Nonsense Mutation (SNP) | VAF 31/142 reads (22%) | catalogued as COSV64595161; called by muse, mutect2, varscan2
- AHDC1 | c.2219G>C p.R740P | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55938608; called by muse, varscan2
- AKAP13 | c.6520C>A p.L2174I (on ENST00000394518 / NM_007200.5; = p.L2178I on NM_006738.6) | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs772823353, COSV63455379; called by muse, mutect2, varscan2
- AKAP6 | c.3325G>T p.E1109* | Nonsense Mutation (SNP) | VAF 95/370 reads (26%) | catalogued as COSV55212455; called by muse, mutect2, varscan2
- AKNA | c.507G>T p.R169S | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as rs1451720540, COSV56312407; called by muse, mutect2, varscan2
- AL592490.1 | c.668C>A p.P223H | Missense Mutation (SNP) | VAF 87/243 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV69426027; called by muse, mutect2, varscan2
- ALB | c.1549G>C p.V517L | Missense Mutation (SNP) | VAF 99/441 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV55737735; called by muse, mutect2, varscan2
- ALCAM | c.1537G>C p.E513Q | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.052); catalogued as COSV100064909, COSV60247763; called by muse, mutect2, varscan2
- ALG2 | c.1037C>T p.S346L | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs544811110, COSV53059689; called by muse, mutect2, varscan2
- ALKBH8 | c.419T>C p.V140A | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs375393669; called by mutect2, varscan2
- AMER3 | c.1258G>T p.D420Y | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58466467; called by muse, mutect2, varscan2
- AMPH | c.1154G>T p.W385L | Missense Mutation (SNP) | VAF 78/285 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57740661; called by muse, mutect2, varscan2
- AMY1C | c.971G>T p.G324V | Missense Mutation (SNP) | VAF 142/779 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs775987541, COSV64407067; called by muse, mutect2, varscan2
- ANKRD55 | c.1578C>A p.H526Q | Missense Mutation (SNP) | VAF 128/397 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV61946418; called by muse, mutect2, varscan2
- ARAF | c.724G>T p.D242Y | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.174); catalogued as COSV51692394; called by muse, mutect2, varscan2
- ARHGAP21 | c.3108G>T p.Q1036H | Missense Mutation (SNP) | VAF 28/242 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57605364; called by muse, mutect2, varscan2
- ARHGAP5 | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 54/223 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745460443, COSV100565208; called by muse, mutect2, varscan2
- ARHGAP5 | c.323G>C p.R108P | Missense Mutation (SNP) | VAF 52/217 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100565211; called by muse, mutect2, varscan2
- ARSH | c.889G>T p.D297Y | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66962878; called by muse, mutect2, varscan2
- ASAH2 | c.1013A>T p.Q338L | Missense Mutation (SNP) | VAF 212/596 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.307); catalogued as COSV61483237; called by muse, mutect2, varscan2
- ASCC3 | c.3324G>T p.R1108S | Missense Mutation (SNP) | VAF 68/137 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.143); catalogued as COSV61228072, COSV61230718; called by muse, mutect2, varscan2
- ASIC1 | c.838C>A p.L280I | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.658); catalogued as COSV57317675; called by muse, mutect2, varscan2
- ASTN1 | c.1720G>C p.D574H | Missense Mutation (SNP) | VAF 85/308 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56067848, COSV99923523; called by muse, mutect2, varscan2
- ASTN1 | c.1066G>C p.D356H | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.825); catalogued as COSV56067864, COSV99920404; called by muse, mutect2, varscan2
- ATOH8 | c.944G>C p.R315P | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV60400271, COSV60401082; called by muse, mutect2, varscan2
- ATP1A4 | c.2544T>A p.D848E | Missense Mutation (SNP) | VAF 66/211 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.058); catalogued as COSV63626364; called by muse, mutect2, varscan2
- ATP7A | c.1012G>T p.V338L | Missense Mutation (SNP) | VAF 120/208 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV58445675; called by muse, mutect2, varscan2
- ATRNL1 | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 569/1431 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV61803273; called by muse, mutect2, varscan2
- B3GALT1 | c.766C>A p.L256I | Missense Mutation (SNP) | VAF 82/295 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); catalogued as COSV59908572; called by muse, mutect2, varscan2
- BAZ2B | c.4154G>C p.R1385P | Missense Mutation (SNP) | VAF 58/316 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58599832; called by muse, mutect2, varscan2
- BBOX1 | c.892A>T p.T298S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.97); PolyPhen benign (0.006); catalogued as COSV54190827; called by muse, mutect2, varscan2
- BBS2 | c.1005G>T p.Q335H | Missense Mutation (SNP) | VAF 154/624 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55326225; called by muse, varscan2
- BCL11A | c.293C>A p.P98H | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867919413, COSV59629057; called by muse, mutect2, varscan2
- BCLAF1 | c.2153G>T p.S718I | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV50357533; called by muse, mutect2, varscan2
- BTBD11 | c.2923-2A>T p.X975_splice (on ENST00000280758 / NM_001018072.2; = p.X512_splice on NM_001017523.2) | Splice Site (SNP) | VAF 148/336 reads (44%) | catalogued as COSV55023511; called by muse, mutect2, varscan2
- BUD23 | c.281G>T p.R94L | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781981931, COSV56094883, COSV56096546; called by muse, mutect2, varscan2
- C9orf64 | c.697A>T p.S233C | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.819); catalogued as COSV59032475; called by muse, mutect2, varscan2
- CACNA1B | c.4975G>T p.E1659* | Nonsense Mutation (SNP) | VAF 13/57 reads (23%) | catalogued as rs745458852, COSV53124332, COSV53145854; called by muse, mutect2, varscan2
- CACNA1E | c.549C>A p.H183Q | Missense Mutation (SNP) | VAF 62/171 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV62390271, COSV62392401; called by muse, mutect2, varscan2
- CACNA1H | c.4283G>T p.R1428M | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61989207; called by muse, mutect2, varscan2
- CACNA2D1 | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 118/477 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.115); catalogued as COSV62378485; called by muse, mutect2, varscan2
- CAMTA1 | c.4324A>G p.S1442G | Missense Mutation (SNP) | VAF 45/201 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV57897973, COSV57908538; called by muse, mutect2, varscan2
- CAPS2 | c.1504G>T p.D502Y | Missense Mutation (SNP) | VAF 103/243 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60825249; called by muse, mutect2, varscan2
- CASKIN1 | c.989del p.G330Afs*49 | Frame Shift Del (DEL) | VAF 4/19 reads (21%) | catalogued as COSV58870304; called by mutect2, pindel, varscan2
- CCDC112 | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65473072; called by muse, mutect2, varscan2
- CCDC88A | c.3090G>T p.W1030C | Missense Mutation (SNP) | VAF 324/563 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55060963; called by muse, mutect2, varscan2
- CCER1 | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV62646671; called by muse, mutect2, varscan2
- CD1D | c.411A>T p.Q137H | Missense Mutation (SNP) | VAF 132/545 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); catalogued as COSV63808934; called by muse, mutect2, varscan2
- CD40LG | c.53C>G p.P18R | Missense Mutation (SNP) | VAF 334/469 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as COSV65698431; called by muse, mutect2, varscan2
- CD8A | c.211C>G p.L71V | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.067); catalogued as COSV52157269; called by muse, mutect2, varscan2
- CDH18 | c.367del p.H123Tfs*59 | Frame Shift Del (DEL) | VAF 48/316 reads (15%) | catalogued as COSV56910516; called by mutect2, pindel, varscan2
- CDH2 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.076); catalogued as COSV52279077; called by muse, mutect2, varscan2
- CDH26 | c.1354G>T p.E452* | Nonsense Mutation (SNP) | VAF 39/126 reads (31%) | catalogued as COSV54846331; called by muse, mutect2, varscan2
- CDH7 | c.1233G>C p.V411= | Splice Region (SNP) | VAF 96/262 reads (37%) | catalogued as COSV59885406; called by muse, mutect2, varscan2
- CDH8 | c.1159G>T p.E387* | Nonsense Mutation (SNP) | VAF 160/402 reads (40%) | catalogued as COSV54851718, COSV54864046; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4724G>T p.R1575I | Missense Mutation (SNP) | VAF 45/445 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV62573936; called by muse, mutect2, varscan2
- CELA2B | c.389C>A p.P130H | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.063); catalogued as COSV65545579; called by muse, varscan2
- CEMIP2 | c.2709G>T p.M903I | Missense Mutation (SNP) | VAF 57/271 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV65484506; called by muse, mutect2, varscan2
- CENPK | c.587A>G p.K196R | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.153); catalogued as COSV54468054; called by muse, mutect2, varscan2
- CEP135 | c.2950C>T p.L984F | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57259742; called by muse, mutect2
- CES5A | c.1566C>A p.D522E (on ENST00000290567 / NM_001143685.2; = p.D472E on NM_145024.3) | Missense Mutation (SNP) | VAF 680/1709 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV51865947; called by muse, mutect2, varscan2
- CFAP61 | c.2893A>G p.T965A | Missense Mutation (SNP) | VAF 229/797 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV55627679, COSV55627700; called by muse, mutect2, varscan2
- CHD9 | c.7181A>G p.E2394G (on ENST00000398510 / NM_001382353.1; = p.E2378G on NM_025134.7) | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.932); catalogued as COSV54609917; called by muse, mutect2, varscan2
- CHI3L2 | c.653G>T p.W218L | Missense Mutation (SNP) | VAF 48/202 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.313); catalogued as COSV63873908; called by muse, mutect2, varscan2
- CHL1 | c.427G>T p.V143L | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV56592357; called by muse, mutect2, varscan2
- CHRD | c.2197-1G>T p.X733_splice | Splice Site (SNP) | VAF 17/54 reads (31%) | catalogued as COSV52607456; called by muse, mutect2, varscan2
- CHST9 | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 62/190 reads (33%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as COSV52436090; called by muse, mutect2, varscan2
- CIZ1 | c.941G>C p.R314P | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.826); catalogued as COSV52971275, COSV99477027; called by muse, mutect2, varscan2
- CKAP4 | c.1210C>G p.Q404E | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV65172445; called by muse, mutect2, varscan2
- CLIC2 | c.294-1G>C p.X98_splice | Splice Site (SNP) | VAF 46/104 reads (44%) | catalogued as COSV58936423; called by muse, mutect2, varscan2
- CNGA1 | c.826C>G p.R276G | Missense Mutation (SNP) | VAF 44/199 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62054132; called by muse, mutect2, varscan2
- CNGA2 | c.1102G>A p.V368M | Missense Mutation (SNP) | VAF 248/350 reads (71%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1433831802, COSV61702966; called by muse, mutect2, varscan2
- CNTN1 | c.2894C>G p.P965R | Missense Mutation (SNP) | VAF 359/814 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV61639236; called by muse, mutect2, varscan2
- COL12A1 | c.7354G>T p.G2452W | Missense Mutation (SNP) | VAF 70/324 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59395023; called by muse, mutect2, varscan2
- COL12A1 | c.1428G>T p.R476S | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as COSV59395030; called by muse, mutect2, varscan2
- COL12A1 | c.659-1G>T p.X220_splice | Splice Site (SNP) | VAF 13/77 reads (17%) | catalogued as COSV59395039; called by muse, mutect2, varscan2
- COL3A1 | c.1324G>T p.E442* | Nonsense Mutation (SNP) | VAF 44/170 reads (26%) | catalogued as COSV58586894, COSV58587645; called by muse, mutect2, varscan2
- COL4A1 | c.464T>A p.M155K | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.91); PolyPhen benign (0.083); catalogued as COSV65424933; called by muse, mutect2, varscan2
- COL6A6 | c.4504C>A p.R1502S | Missense Mutation (SNP) | VAF 82/350 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV62023950; called by muse, mutect2, varscan2
- COL8A2 | c.1810G>T p.G604C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV57441534; called by muse, mutect2, varscan2
- CPQ | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 134/313 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55144599; called by muse, mutect2, varscan2
- CPQ | c.700A>T p.I234F | Missense Mutation (SNP) | VAF 417/996 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55144607, COSV55159636; called by muse, mutect2, varscan2
- CRISP1 | c.570G>C p.K190N | Missense Mutation (SNP) | VAF 58/381 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.024); catalogued as COSV59993471; called by muse, mutect2, varscan2
- CSMD1 | c.10181C>A p.S3394* (on ENST00000520002; = p.S3393* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 60/181 reads (33%) | catalogued as COSV59317025; called by muse, mutect2, varscan2
- CSMD3 | c.4595G>T p.G1532V (on ENST00000297405 / NM_001363185.1; = p.G1428V on NM_052900.3) | Missense Mutation (SNP) | VAF 75/179 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV52167298, COSV52262541; called by muse, mutect2, varscan2
- CSMD3 | c.1177G>T p.E393* | Nonsense Mutation (SNP) | VAF 42/241 reads (17%) | catalogued as COSV52167315, COSV52262612; called by muse, mutect2, varscan2
- CSPP1 | c.1605G>C p.R535S (on ENST00000676605; = p.R494S on NM_024790.6) | Missense Mutation (SNP) | VAF 135/541 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as COSV51583839; called by muse, mutect2, varscan2
- CTCFL | c.1840G>T p.E614* | Nonsense Mutation (SNP) | VAF 116/304 reads (38%) | catalogued as COSV54773746, COSV54778538; called by muse, mutect2, varscan2
- CTNND2 | c.2882C>A p.T961K | Missense Mutation (SNP) | VAF 129/392 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.787); catalogued as COSV58885334, COSV58893607; called by muse, mutect2, varscan2
- CTRB2 | c.719C>A p.T240N | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as rs755921589, COSV57315595; called by muse, mutect2, varscan2
- CXCL6 | c.164C>T p.T55M | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.766); catalogued as rs931779886, COSV56902940; called by muse, mutect2, varscan2
- CYLD | c.913G>T p.A305S | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV61094361; called by muse, mutect2, varscan2
- CYP11B2 | c.1342C>A p.R448S | Missense Mutation (SNP) | VAF 31/190 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59995677; called by muse, mutect2, varscan2
- CYP4A11 | c.1417C>A p.L473M | Missense Mutation (SNP) | VAF 224/797 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.91); catalogued as COSV60223321; called by muse, mutect2, varscan2
- DAB1 | c.131C>A p.A44D | Missense Mutation (SNP) | VAF 62/223 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59727031; called by muse, varscan2
- DAB1 | c.71A>T p.Q24L | Missense Mutation (SNP) | VAF 51/217 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.169); catalogued as COSV59727054; called by muse, varscan2
- DCAF4L2 | c.345C>A p.Y115* | Nonsense Mutation (SNP) | VAF 92/280 reads (33%) | catalogued as rs1351649547, COSV60478313; called by muse, mutect2, varscan2
- DDIAS | c.2743G>T p.G915C | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV61271970; called by muse, mutect2, varscan2
- DDX42 | c.181A>C p.K61Q | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.425); catalogued as COSV63790036; called by muse, mutect2, varscan2
- DGKG | c.1106G>C p.C369S | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53964351; called by muse, mutect2, varscan2
- DGKI | c.2498-1G>A p.X833_splice | Splice Site (SNP) | VAF 41/171 reads (24%) | catalogued as COSV55947926; called by muse, mutect2, varscan2
- DGKI | c.2377C>T p.Q793* | Nonsense Mutation (SNP) | VAF 123/569 reads (22%) | catalogued as COSV55947934, COSV55957104; called by muse, mutect2, varscan2
- DHX30 | c.439G>T p.G147C (on ENST00000445061 / NM_138615.3; = p.G108C on NM_014966.3) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.765); catalogued as COSV62394347; called by muse, mutect2, varscan2
- DLGAP2 | c.1381G>T p.A461S | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.243); catalogued as rs754587148, COSV70097632; called by mutect2, varscan2
- DMXL1 | c.1369G>T p.G457C | Missense Mutation (SNP) | VAF 65/171 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.395); catalogued as COSV60710469; called by muse, mutect2, varscan2
- DNAJC11 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 95/456 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.014); catalogued as rs754043204, COSV53786382; called by muse, mutect2, varscan2
- DOCK9 | c.3143A>G p.Y1048C (on ENST00000376460 / NM_001366676.2; = p.Y1049C on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/208 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as rs777905478, COSV59627383; called by muse, varscan2
- DPEP3 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.178); catalogued as COSV52051182; called by muse, mutect2, varscan2
- DPT | c.502A>T p.I168F | Missense Mutation (SNP) | VAF 439/1489 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as COSV63189905; called by muse, mutect2, varscan2
- DRD5 | c.976C>A p.P326T | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.197); catalogued as rs1244039040, COSV58577808; called by muse, mutect2, varscan2
- DYSF | c.3704G>T p.G1235V | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV50308034; called by muse, mutect2, varscan2
- EGR2 | c.74T>C p.I25T | Missense Mutation (SNP) | VAF 64/197 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV54346768; called by muse, mutect2, varscan2
- EPAS1 | c.2591G>T p.R864I | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV55386199; called by muse, mutect2, varscan2
- EPB41L3 | c.1727G>T p.R576I | Missense Mutation (SNP) | VAF 76/259 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.143); catalogued as COSV59451795; called by muse, mutect2, varscan2
- EPHA3 | c.2249G>T p.R750L | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60692867, COSV60703794; called by muse, mutect2, varscan2
- EPHB6 | c.2248G>T p.E750* | Nonsense Mutation (SNP) | VAF 13/85 reads (15%) | catalogued as COSV63891585; called by muse, mutect2, varscan2
- ESM1 | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 59/198 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.651); catalogued as COSV67318538; called by muse, mutect2, varscan2
- EYS | c.1582C>A p.H528N | Missense Mutation (SNP) | VAF 79/333 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV60984003; called by muse, mutect2, varscan2
- FAM222B | c.55A>T p.T19S | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.051); catalogued as COSV57930087, COSV57932226; called by muse, mutect2, varscan2
- FAT1 | c.3114_3115insT p.E1039* | Frame Shift Ins (INS) | VAF 62/288 reads (22%) | catalogued as COSV101499294; called by mutect2, pindel, varscan2
- FBN2 | c.1569G>T p.M523I | Missense Mutation (SNP) | VAF 78/246 reads (32%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.48); catalogued as COSV52509937; called by muse, mutect2, varscan2
- FBN2 | c.1161G>T p.Q387H | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52509951; called by muse, mutect2, varscan2
- FBXL7 | c.754A>C p.T252P | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV61645321; called by muse, mutect2, varscan2
- FBXO47 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV65241681; called by muse, mutect2, varscan2
- FERD3L | c.275C>A p.P92H | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs202202177, COSV51762449; called by muse, mutect2, varscan2
- FGB | c.283T>A p.C95S | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM153764, COSV57418172; called by muse, mutect2, varscan2
- FGF13 | c.704G>C p.G235A | Missense Mutation (SNP) | VAF 429/670 reads (64%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.41); catalogued as COSV59545193; called by muse, mutect2, varscan2
- FGFRL1 | c.728G>T p.R243L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.196); catalogued as COSV53257428, COSV53259785; called by muse, varscan2
- FHOD3 | c.4039T>A p.W1347R (on ENST00000359247 / NM_001281739.3; = p.W1364R on NM_025135.5) | Missense Mutation (SNP) | VAF 76/182 reads (42%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.997); catalogued as COSV57172148; called by muse, mutect2, varscan2
- FILIP1 | c.2539G>T p.V847L | Missense Mutation (SNP) | VAF 162/570 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV52724534, COSV52728525; called by muse, mutect2, varscan2
- FLG | c.9987C>G p.D3329E | Missense Mutation (SNP) | VAF 542/2147 reads (25%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.549); catalogued as COSV64241106; called by muse, mutect2, varscan2
- FLG | c.5279G>C p.G1760A | Missense Mutation (SNP) | VAF 234/677 reads (35%) | SIFT tolerated (0.93); PolyPhen probably damaging (0.987); catalogued as rs778313267, COSV64241109; called by muse, mutect2, varscan2
- FRMD3 | c.1086G>C p.Q362H | Missense Mutation (SNP) | VAF 42/169 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.03); catalogued as COSV58460590; called by muse, mutect2, varscan2
- FRMPD1 | c.4003A>T p.S1335C | Missense Mutation (SNP) | VAF 33/214 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV66700210; called by muse, mutect2, varscan2
- FRMPD4 | c.1865A>G p.Y622C | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.711); catalogued as COSV66214322; called by muse, mutect2, varscan2
- GABRG2 | c.49C>A p.P17T | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.096); catalogued as COSV62717664; called by muse, mutect2, varscan2
- GATA3 | c.803C>A p.A268E | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60517986; called by muse, mutect2, varscan2
- GFRAL | c.613C>A p.L205I | Missense Mutation (SNP) | VAF 264/804 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV61230628; called by muse, mutect2, varscan2
- GIMAP8 | c.1547G>T p.R516L | Missense Mutation (SNP) | VAF 56/204 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.844); catalogued as COSV100217370, COSV56231132; called by muse, mutect2, varscan2
- GJA1 | c.942T>G p.S314R | Missense Mutation (SNP) | VAF 94/305 reads (31%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.98); catalogued as COSV56997831; called by muse, mutect2, varscan2
- GLRB | c.601C>A p.L201M | Missense Mutation (SNP) | VAF 76/228 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.825); catalogued as COSV52416391; called by muse, mutect2, varscan2
- GPC4 | c.1017G>T p.Q339H | Missense Mutation (SNP) | VAF 259/655 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV63697730; called by muse, mutect2, varscan2
- GPM6A | c.815A>T p.E272V | Missense Mutation (SNP) | VAF 107/366 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54540704; called by muse, mutect2, varscan2
- GPR148 | c.916G>T p.E306* | Nonsense Mutation (SNP) | VAF 19/143 reads (13%) | catalogued as COSV59308139; called by muse, mutect2, varscan2
- GPR31 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV64761394; called by muse, mutect2, varscan2
- GPR32 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54514383; called by muse, mutect2, varscan2
- GPR55 | c.438G>T p.W146C | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV67407632; called by muse, mutect2, varscan2
- GRM8 | c.2269A>G p.I757V | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.088); catalogued as COSV58822524, COSV58825369; called by muse, mutect2, varscan2
- HECW1 | c.778G>T p.V260L | Missense Mutation (SNP) | VAF 27/254 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV67824814, COSV67828356; called by muse, mutect2, varscan2
- HERC1 | c.5188C>G p.Q1730E | Missense Mutation (SNP) | VAF 102/224 reads (46%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.9); catalogued as COSV71247608; called by muse, mutect2, varscan2
- HERPUD2 | c.308G>A p.S103N | Missense Mutation (SNP) | VAF 32/243 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV60944922; called by muse, mutect2, varscan2
- HGF | c.294G>T p.W98C | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs1311872364, COSV55948663, COSV55956826; called by muse, mutect2, varscan2
- HHIPL1 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58090224; called by muse, mutect2, varscan2
- HHIPL2 | c.1392G>T p.W464C | Missense Mutation (SNP) | VAF 117/426 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58564929; called by muse, mutect2, varscan2
- HJURP | c.1054G>T p.G352C | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100982588; called by muse, mutect2
- HMCN1 | c.14451G>T p.W4817C | Missense Mutation (SNP) | VAF 51/232 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54897062; called by muse, mutect2, varscan2
- HNRNPA1L2 | c.428G>T p.G143V | Missense Mutation (SNP) | VAF 60/157 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as COSV61255241; called by muse, mutect2, varscan2
- HOXA5 | c.787G>T p.A263S | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.191); catalogued as COSV56072983; called by muse, mutect2, varscan2
- HPS3 | c.980C>G p.T327R | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.047); catalogued as rs575943583, COSV56054075; called by muse, mutect2, varscan2
- HSD3B2 | c.481G>C p.A161P | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM154062, COSV65593074; called by muse, mutect2, varscan2
- IGFLR1 | c.751T>C p.S251P | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as COSV53074715; called by muse, mutect2, varscan2
- IL27 | c.259C>A p.L87I | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV60488621, COSV60490263; called by muse, mutect2, varscan2
- ING3 | c.668G>C p.G223A | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.85); PolyPhen probably damaging (0.987); catalogued as COSV59950912; called by muse, mutect2, varscan2
- INSL4 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 110/219 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.065); catalogued as COSV53328996; called by muse, mutect2, varscan2
- INTS5 | c.1857G>T p.E619D | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.281); catalogued as COSV57950585, COSV57951345; called by muse, mutect2, varscan2
- ITGA8 | c.2357A>T p.Q786L | Missense Mutation (SNP) | VAF 48/320 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.816); catalogued as COSV65228137; called by muse, mutect2, varscan2
- ITPR1 | c.2940G>T p.Q980H (on ENST00000354582; = p.Q965H on NM_002222.7) | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV56979356; called by muse, mutect2, varscan2
- JAM2 | c.176C>A p.S59Y | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as rs1393032305, COSV57257216; called by muse, mutect2, varscan2
- KCNC4 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | catalogued as COSV100873611, COSV63925558; called by mutect2, varscan2
- KCNG1 | c.134G>T p.R45L | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as COSV65368941; called by muse, mutect2, varscan2
- KCNH3 | c.2312G>A p.R771H | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.39); PolyPhen benign (0.289); catalogued as rs368671377; called by mutect2, varscan2
- KCNK10 | c.814G>T p.V272F | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV56644081; called by muse, mutect2, varscan2
- KCNQ2 | c.766G>T p.G256W | Missense Mutation (SNP) | VAF 54/227 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV60433724; called by muse, mutect2, varscan2
- KCNT2 | c.3398C>A p.T1133N | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.911); catalogued as COSV54077281; called by muse, mutect2, varscan2
- KDM2B | c.2233G>T p.G745C | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV65640334; called by muse, mutect2, varscan2
- KIAA1210 | c.137G>T p.C46F | Missense Mutation (SNP) | VAF 55/90 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); catalogued as COSV68176923; called by muse, mutect2, varscan2
- KIAA1614 | c.554C>T p.P185L | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs372280369; called by muse, mutect2, varscan2
- KIRREL1 | c.1562A>T p.Y521F | Missense Mutation (SNP) | VAF 88/228 reads (39%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.985); catalogued as COSV63286856; called by muse, mutect2, varscan2
- KLHL22 | c.1121C>T p.P374L | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV61020729; called by muse, mutect2, varscan2
- KLHL6 | c.845G>T p.R282M | Missense Mutation (SNP) | VAF 88/327 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV58066125; called by muse, mutect2, varscan2
- KLK15 | c.382C>A p.P128T | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.53); catalogued as COSV56826767; called by muse, mutect2, varscan2
- KMT2D | c.8896C>T p.R2966W | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.232); catalogued as rs970105771, COSV56435300; called by muse, mutect2, varscan2
- KRTAP19-6 | c.90C>A p.Y30* | Nonsense Mutation (SNP) | VAF 192/618 reads (31%) | catalogued as COSV61844019; called by muse, mutect2, varscan2
- LAMA2 | c.958C>A p.Q320K | Missense Mutation (SNP) | VAF 67/310 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.055); catalogued as COSV70345928; called by muse, mutect2, varscan2
- LAMA3 | c.3023G>T p.R1008L | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as COSV100555764, COSV58067784; called by muse, mutect2, varscan2
- LDLRAD4 | c.594G>T p.M198I | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as COSV63336948; called by muse, mutect2, varscan2
- LEPR | c.2273G>A p.W758* | Nonsense Mutation (SNP) | VAF 71/230 reads (31%) | catalogued as COSV60753390; called by muse, mutect2, varscan2
- LINGO1 | c.989C>A p.A330D | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV62436888; called by muse, mutect2, varscan2
- LPIN3 | c.1805G>T p.R602L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.043); catalogued as COSV60036030; called by muse, mutect2, varscan2
- LRP1B | c.13531G>T p.D4511Y | Missense Mutation (SNP) | VAF 141/434 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as COSV67197697, COSV67213000; called by muse, mutect2, varscan2
- LRP1B | c.6203A>G p.D2068G | Missense Mutation (SNP) | VAF 169/551 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.265); catalogued as COSV67213003; called by muse, mutect2, varscan2
- LRP1B | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs747406586, COSV67213007, COSV67247430; called by muse, mutect2, varscan2
- LRRC8D | c.1133T>G p.F378C | Missense Mutation (SNP) | VAF 45/344 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV61578925; called by muse, mutect2, varscan2
- LRWD1 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.232); catalogued as rs751880306, COSV52960845; called by muse, mutect2, varscan2
- LTBP2 | c.5045C>A p.P1682H | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV56207549; called by muse, mutect2, varscan2
- LVRN | c.2199G>T p.R733S | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV63497124; called by muse, mutect2, varscan2
- LY75 | c.944C>T p.S315F | Missense Mutation (SNP) | VAF 63/233 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55104981; called by muse, mutect2, varscan2
- LY9 | c.1006C>A p.H336N | Missense Mutation (SNP) | VAF 66/181 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs1353333866, COSV54433687; called by muse, mutect2, varscan2
- MAGEC3 | c.1735C>A p.Q579K | Missense Mutation (SNP) | VAF 127/198 reads (64%) | SIFT tolerated (0.1); PolyPhen benign (0.172); catalogued as COSV53579572, COSV68923918; called by muse, mutect2, varscan2
- MAGEF1 | c.377G>T p.R126L | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.29); catalogued as rs766942431, COSV58633693; called by muse, mutect2, varscan2
- MANBA | c.2590G>A p.D864N (on ENST00000642252; = p.D818N on NM_005908.4) | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.031); catalogued as COSV56963452, COSV56964980; called by muse, mutect2, varscan2
- MAP2K4 | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 157/477 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as COSV62257055; called by muse, mutect2, varscan2
- MAPK4 | c.751G>T p.E251* | Nonsense Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as COSV101246098, COSV68541949; called by muse, mutect2, varscan2
- MAPT | c.1513G>T p.A505S (on ENST00000262410 / NM_001377265.1; = p.A430S on NM_016835.4) | Missense Mutation (SNP) | VAF 61/256 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52240008; called by muse, mutect2, varscan2
- MARCO | c.1199G>T p.G400V | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100503253, COSV59053977; called by muse, mutect2, varscan2
- MDC1 | c.1603A>G p.I535V | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64524390; called by muse, mutect2, varscan2
- MED12L | c.6205C>T p.Q2069* | Nonsense Mutation (SNP) | VAF 15/61 reads (25%) | catalogued as COSV56377354; called by muse, mutect2, varscan2
- MEGF10 | c.2165C>A p.A722D | Missense Mutation (SNP) | VAF 113/318 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV57248550; called by muse, mutect2, varscan2
- MFAP4 | c.297C>A p.Y99* | Nonsense Mutation (SNP) | VAF 20/74 reads (27%) | catalogued as COSV55190272; called by muse, mutect2, varscan2
- MMAA | c.997G>T p.E333* | Nonsense Mutation (SNP) | VAF 101/416 reads (24%) | catalogued as COSV55579949; called by muse, mutect2, varscan2
- MMRN1 | c.2320A>T p.T774S | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV53336968; called by muse, mutect2, varscan2
- MOXD1 | c.616C>A p.Q206K | Missense Mutation (SNP) | VAF 73/294 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV60943935; called by muse, mutect2, varscan2
- MROH2B | c.4579C>G p.L1527V | Missense Mutation (SNP) | VAF 107/285 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV68183427; called by muse, mutect2, varscan2
- MRPL39 | c.599G>T p.R200L | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV100220785, COSV56260590; called by muse, mutect2, varscan2
- MUC13 | c.475G>T p.G159C | Missense Mutation (SNP) | VAF 124/508 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.773); catalogued as COSV60699271; called by muse, mutect2, varscan2
- MUC16 | c.37367T>A p.V12456E | Missense Mutation (SNP) | VAF 407/1086 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV67462652; called by muse, mutect2, varscan2
- MUC16 | c.34195G>T p.D11399Y | Missense Mutation (SNP) | VAF 370/976 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.272); catalogued as COSV67462655; called by muse, mutect2, varscan2
- MUC17 | c.850G>A p.V284M | Missense Mutation (SNP) | VAF 113/785 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs201857499; called by muse, mutect2, varscan2
- MUC17 | c.9250A>G p.S3084G | Missense Mutation (SNP) | VAF 98/506 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.483); catalogued as COSV60287276; called by muse, mutect2, varscan2
- MXRA5 | c.7997A>T p.Q2666L | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.233); catalogued as COSV54233530; called by muse, mutect2, varscan2
- MYH11 | c.3483C>A p.S1161R | Missense Mutation (SNP) | VAF 47/183 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as COSV55551562; called by muse, mutect2, varscan2
- MYH2 | c.3518G>T p.R1173L | Missense Mutation (SNP) | VAF 52/149 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55437079, COSV55445634; called by muse, mutect2, varscan2
- MYH7 | c.4243G>T p.E1415* | Nonsense Mutation (SNP) | VAF 35/118 reads (30%) | catalogued as COSV62516678, COSV62520715; called by muse, mutect2, varscan2
- MYO3B | c.3995C>A p.S1332Y | Missense Mutation (SNP) | VAF 30/246 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.424); catalogued as COSV58702070; called by muse, mutect2, varscan2
- NAPB | c.523C>G p.L175V | Missense Mutation (SNP) | VAF 66/408 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV65464399; called by muse, mutect2, varscan2
- NBAS | c.4289A>T p.Q1430L | Missense Mutation (SNP) | VAF 134/352 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as COSV55720030; called by muse, mutect2, varscan2
- NCAM1 | c.1247C>A p.P416Q (on ENST00000316851 / NM_181351.5; = p.P406Q on NM_000615.7) | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57515588; called by muse, mutect2, varscan2
- NCAM2 | c.1960G>T p.E654* | Nonsense Mutation (SNP) | VAF 53/185 reads (29%) | catalogued as COSV53072144, COSV53105366; called by muse, mutect2, varscan2
- NCOA3 | c.2872A>G p.I958V | Missense Mutation (SNP) | VAF 180/419 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV59068184; called by muse, mutect2, varscan2
- NDST3 | c.1523C>A p.T508N | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1165879333, COSV56618034; called by muse, mutect2, varscan2
- NEB | c.980A>T p.Q327L | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.98); catalogued as COSV51237655; called by muse, mutect2
- NELL1 | c.879G>C p.R293S | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV54260392; called by muse, mutect2, varscan2
- NEU2 | c.201+2T>A p.X67_splice | Splice Site (SNP) | VAF 3/9 reads (33%) | catalogued as COSV52092599; called by muse, mutect2
- NEXMIF | c.3010A>G p.S1004G | Missense Mutation (SNP) | VAF 48/252 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as COSV50029117; called by muse, mutect2, varscan2
- NLGN1 | c.632G>T p.R211L | Missense Mutation (SNP) | VAF 56/221 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV64332020; called by muse, mutect2, varscan2
- NLRP12 | c.2651A>G p.Q884R | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.022); catalogued as rs766064896, COSV60746769, COSV60750658; called by muse, mutect2, varscan2
- NLRP3 | c.1210T>C p.F404L | Missense Mutation (SNP) | VAF 95/329 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV60223550; called by muse, mutect2, varscan2
- NOD2 | c.1792C>A p.P598T | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.211); catalogued as rs759418926, COSV56050348; called by muse, mutect2
- NR3C2 | c.1515G>T p.E505D | Missense Mutation (SNP) | VAF 45/176 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.04); catalogued as COSV60989571; called by muse, mutect2, varscan2
- NRCAM | c.1660T>A p.Y554N (on ENST00000379028 / NM_001371124.1; = p.Y548N on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 134/508 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.103); catalogued as COSV61035672; called by muse, mutect2, varscan2
- OARD1 | c.332G>T p.G111V | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV55107396, COSV55107660; called by muse, mutect2, varscan2
- OBSCN | c.14793G>C p.W4931C | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52769978; called by muse, varscan2
- OPN5 | c.388G>T p.D130Y | Missense Mutation (SNP) | VAF 60/243 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.438); catalogued as COSV55245326; called by muse, mutect2, varscan2
- OR10G8 | c.393C>A p.Y131* | Nonsense Mutation (SNP) | VAF 258/1092 reads (24%) | catalogued as COSV70908487, COSV70909187; called by muse, mutect2, varscan2
- OR10S1 | c.235C>T p.L79F | Missense Mutation (SNP) | VAF 85/323 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73342766; called by muse, mutect2, varscan2
- OR13H1 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 325/1170 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58547552; called by muse, mutect2, varscan2
- OR14I1 | c.636G>T p.M212I | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV61199519, COSV61199705; called by muse, mutect2, varscan2
- OR14I1 | c.541C>T p.H181Y | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1040170550, COSV61199525; called by muse, mutect2
- OR1D5 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 45/265 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101643419; called by muse, mutect2, varscan2
- OR2L8 | c.43G>T p.G15W | Missense Mutation (SNP) | VAF 218/649 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61726605; called by muse, mutect2, varscan2
- OR4A15 | c.715G>T p.A239S | Missense Mutation (SNP) | VAF 152/593 reads (26%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.048); catalogued as COSV59033609; called by muse, mutect2, varscan2
- OR4C6 | c.284G>C p.C95S | Missense Mutation (SNP) | VAF 128/437 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100051812, COSV58603631; called by muse, mutect2, varscan2
- OR4C6 | c.884C>A p.A295D | Missense Mutation (SNP) | VAF 115/392 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as COSV58602805, COSV58603641; called by muse, mutect2, varscan2
- OR4K14 | c.322A>G p.T108A | Missense Mutation (SNP) | VAF 61/185 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV59292751; called by muse, mutect2, varscan2
- OR51B2 | c.373C>A p.R125S | Missense Mutation (SNP) | VAF 109/288 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0.317); catalogued as rs376911782, COSV60916517, COSV60917202; called by muse, mutect2, varscan2
- OR5B12 | c.82G>T p.V28F | Missense Mutation (SNP) | VAF 148/599 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.27); catalogued as COSV56904845; called by muse, mutect2, varscan2
- OR5D16 | c.874T>A p.Y292N | Missense Mutation (SNP) | VAF 63/277 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65721830; called by muse, mutect2, varscan2
- OR5H1 | c.345G>T p.L115F | Missense Mutation (SNP) | VAF 230/919 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63402313; called by muse, mutect2, varscan2
- OR5T3 | c.727G>C p.A243P | Missense Mutation (SNP) | VAF 211/768 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.16); catalogued as COSV57380398; called by muse, mutect2, varscan2
- OR8K5 | c.526C>A p.H176N | Missense Mutation (SNP) | VAF 81/327 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.582); catalogued as COSV57888620; called by muse, mutect2, varscan2
- PANX3 | c.914A>G p.Y305C | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745336792, COSV52511919; called by muse, mutect2, varscan2
- PAPPA | c.1606G>A p.E536K | Missense Mutation (SNP) | VAF 143/414 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV60282275; called by muse, mutect2, varscan2
- PAPPA | c.2018C>A p.A673E | Missense Mutation (SNP) | VAF 217/567 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.289); catalogued as rs1236873179, COSV60282285, COSV60290260; called by muse, mutect2, varscan2
- PASD1 | c.1777G>T p.V593L | Missense Mutation (SNP) | VAF 108/306 reads (35%) | SIFT tolerated (0.56); PolyPhen benign (0.051); catalogued as COSV100949686, COSV64855081; called by muse, mutect2, varscan2
- PAX2 | c.55G>A p.G19S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62291079; called by muse, mutect2, varscan2
- PCBP3 | c.1003G>A p.G335R | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68407790; called by muse, mutect2, varscan2
- PCDH11X | c.627G>T p.R209S | Missense Mutation (SNP) | VAF 357/511 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53462015; called by muse, mutect2, varscan2
- PCDH11X | c.3478C>A p.H1160N | Missense Mutation (SNP) | VAF 145/230 reads (63%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV100008402, COSV53462076; called by muse, mutect2, varscan2
- PCDHB8 | c.1827G>T p.K609N | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV50794117, COSV99177170; called by muse, mutect2, varscan2
- PCLO | c.8875G>T p.A2959S | Missense Mutation (SNP) | VAF 96/329 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.082); catalogued as COSV61616151, COSV61632150; called by muse, mutect2, varscan2
- PCOLCE2 | c.1128C>A p.Y376* | Nonsense Mutation (SNP) | VAF 69/327 reads (21%) | catalogued as COSV55998843; called by muse, mutect2, varscan2
- PDE3A | c.2677G>T p.E893* | Nonsense Mutation (SNP) | VAF 52/154 reads (34%) | catalogued as COSV100762045; called by muse, mutect2, varscan2
- PER2 | c.2116G>T p.G706C | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.922); catalogued as rs1201639113, COSV54523270; called by muse, mutect2, varscan2
- PIK3C2G | c.1522G>T p.V508L | Missense Mutation (SNP) | VAF 99/286 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV56807483; called by muse, mutect2, varscan2
- PIK3R3 | c.884T>C p.M295T | Missense Mutation (SNP) | VAF 82/322 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as rs758746746, COSV53106887; called by muse, varscan2
- PIK3R4 | c.2603C>T p.P868L | Missense Mutation (SNP) | VAF 76/276 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV63240708; called by muse, mutect2, varscan2
- PIWIL3 | c.1304C>T p.T435I | Missense Mutation (SNP) | VAF 87/316 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as rs1452287881, COSV59995172; called by muse, mutect2, varscan2
- PJA1 | c.1475A>T p.D492V (on ENST00000361478 / NM_145119.4; = p.D304V on NM_022368.5) | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV64053043; called by muse, mutect2, varscan2
- PKD1L1 | c.6578G>A p.G2193D | Missense Mutation (SNP) | VAF 39/330 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as rs748792415, COSV56963775; called by muse, mutect2, varscan2
- PKD2L2 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0.038); catalogued as COSV51797082; called by muse, mutect2, varscan2
- PKNOX2 | c.1384G>T p.D462Y | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.959); catalogued as rs372201456, COSV53545091; called by muse, mutect2, varscan2
- PLCG1 | c.3029G>T p.R1010L | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54818084, COSV54822887; called by muse, mutect2, varscan2
- PLCXD2 | c.783T>G p.H261Q | Missense Mutation (SNP) | VAF 44/180 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV67339642; called by muse, mutect2, varscan2
- PLEKHA6 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 51/260 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV55331695; called by muse, mutect2, varscan2
- PLEKHH2 | c.3691A>G p.R1231G | Missense Mutation (SNP) | VAF 31/205 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV56752929; called by muse, mutect2, varscan2
- PLEKHM1 | c.2016T>A p.F672L | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV69598812; called by muse, mutect2, varscan2
- PLPPR4 | c.2074A>T p.S692C | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as COSV64565571; called by muse, mutect2, varscan2
- PLXNA4 | c.3665C>A p.S1222Y | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV58110583, COSV58121900; called by muse, mutect2, varscan2
- PLXNA4 | c.1154G>T p.W385L | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58121923; called by muse, mutect2, varscan2
- POLR1B | c.278G>C p.C93S | Missense Mutation (SNP) | VAF 47/202 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.025); catalogued as COSV54497473; called by muse, mutect2, varscan2
- POLR3A | c.449G>T p.C150F | Missense Mutation (SNP) | VAF 77/249 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV64930931; called by muse, mutect2, varscan2
- POM121L12 | c.721G>T p.G241C | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV68692853, COSV68694663; called by muse, mutect2
- POU4F2 | c.975G>T p.E325D | Missense Mutation (SNP) | VAF 59/191 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as rs1172865081, COSV55584066; called by muse, mutect2, varscan2
- PPARGC1A | c.2167del p.R723Vfs*42 | Frame Shift Del (DEL) | VAF 22/209 reads (11%) | catalogued as COSV99337208; called by mutect2, pindel, varscan2
- PPFIA2 | c.3018G>T p.Q1006H | Missense Mutation (SNP) | VAF 53/104 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV61030365; called by muse, mutect2, varscan2
- PPFIA4 | c.1933G>T p.G645C (on ENST00000447715; = p.G646C on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55314478, COSV99690467; called by muse, mutect2, varscan2
- PPP1R26 | c.1745T>G p.L582R | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.748); catalogued as COSV63355453; called by muse, mutect2, varscan2
- PPT2 | c.139G>T p.D47Y | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52997428; called by muse, mutect2
- PRDM14 | c.544C>A p.P182T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.093); catalogued as COSV52570622, COSV52572032; called by mutect2, varscan2
- PREX1 | c.220G>T p.A74S | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100906090, COSV64251261; called by muse, mutect2, varscan2
- PRSS54 | c.655-1G>A p.X219_splice | Splice Site (SNP) | VAF 91/199 reads (46%) | catalogued as COSV99540884; called by muse, mutect2, varscan2
- PSKH2 | c.724G>T p.A242S | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.145); catalogued as COSV52610275, COSV99405143; called by muse, mutect2, varscan2
- PSMD11 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 47/191 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1408778454, COSV55578570; called by muse, mutect2, varscan2
- PTGFR | c.265G>T p.V89L | Missense Mutation (SNP) | VAF 11/380 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.073); catalogued as COSV66114967; called by muse, mutect2
- PTPRC | c.3305G>T p.R1102L | Missense Mutation (SNP) | VAF 95/453 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61410724; called by muse, mutect2, varscan2
- PTPRZ1 | c.3215C>A p.P1072H | Missense Mutation (SNP) | VAF 104/333 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as COSV66429728, COSV66435696; called by muse, mutect2, varscan2
- PZP | c.4391C>A p.S1464Y | Missense Mutation (SNP) | VAF 97/278 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as COSV54359426, COSV54363396; called by muse, mutect2, varscan2
- RAD54B | c.1110G>A p.W370* | Nonsense Mutation (SNP) | VAF 183/531 reads (34%) | catalogued as rs781224724, COSV60250986; called by muse, mutect2, varscan2
- RBM10 | c.457G>T p.G153C | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61307877, COSV61310883; called by muse, mutect2, varscan2
- RBM17 | c.1178G>C p.R393T | Missense Mutation (SNP) | VAF 64/320 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.232); catalogued as COSV65913921; called by muse, mutect2, varscan2
- RBM45 | c.243G>T p.R81S | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.138); catalogued as COSV53720738; called by muse, mutect2, varscan2
- RCBTB2 | c.1090G>T p.A364S | Missense Mutation (SNP) | VAF 72/172 reads (42%) | SIFT tolerated (0.67); PolyPhen benign (0.044); catalogued as COSV60650035, COSV60650255, COSV60651745; called by muse, mutect2, varscan2
- RELN | c.2461C>A p.P821T | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as COSV58999547; called by muse, mutect2, varscan2
- RFC1 | c.1355G>T p.R452L | Missense Mutation (SNP) | VAF 767/2854 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV62899432; called by muse, mutect2, varscan2
- RNF32 | c.914G>A p.G305D | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV58732142; called by muse, mutect2, varscan2
- ROBO4 | c.2981G>A p.C994Y | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV60623611; called by muse, mutect2, varscan2
- ROCK1 | c.697A>G p.T233A | Missense Mutation (SNP) | VAF 82/288 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as COSV67695836; called by muse, mutect2, varscan2
- RYR1 | c.5278C>A p.H1760N | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.474); catalogued as COSV62096019; called by muse, varscan2
- RYR2 | c.3070G>T p.V1024L | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.719); catalogued as rs1291873158, COSV63682678; called by muse, mutect2, varscan2
- RYR2 | c.13343A>C p.E4448A | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.093); catalogued as COSV63682685; called by muse, mutect2
- RYR3 | c.1423C>G p.L475V | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV66779763, COSV66786752; called by muse, mutect2, varscan2
- SALL1 | c.2403C>A p.S801R | Missense Mutation (SNP) | VAF 97/214 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs1237482844, COSV51756751; called by muse, mutect2, varscan2
- SALL4 | c.1331A>T p.E444V | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV53851825; called by muse, mutect2, varscan2
- SATB2 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 76/276 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV53482960; called by muse, mutect2, varscan2
- SCGN | c.349T>A p.Y117N | Missense Mutation (SNP) | VAF 72/192 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58545354; called by muse, mutect2, varscan2
- SCN2A | c.2501G>T p.S834I | Missense Mutation (SNP) | VAF 76/219 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51839446; called by muse, mutect2, varscan2
- SCN4A | c.4390G>A p.G1464R | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.147); catalogued as rs150423825, COSV101438308, COSV71126675; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN7A | c.573G>T p.E191D | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV69271073; called by muse, mutect2, varscan2
- SDR42E1 | c.750G>T p.Q250H | Missense Mutation (SNP) | VAF 87/442 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as COSV61094113, COSV61094899; called by muse, mutect2, varscan2
- SELP | c.1823T>A p.L608Q | Missense Mutation (SNP) | VAF 24/338 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as COSV55251301, COSV99741116; called by muse, mutect2
- SEMA5A | c.2365G>T p.A789S | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.01); catalogued as rs1456126471, COSV66791557; called by muse, mutect2, varscan2
- SEMA6D | c.1422T>G p.H474Q | Missense Mutation (SNP) | VAF 68/203 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV60376485; called by muse, mutect2, varscan2
- SERPINB2 | c.1095G>T p.E365D | Missense Mutation (SNP) | VAF 83/216 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV53072891; called by muse, mutect2, varscan2
- SETX | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 62/248 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56383981; called by muse, mutect2, varscan2
- SF3B1 | c.2876C>T p.A959V | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.881); catalogued as COSV59212892; called by muse, mutect2, varscan2
- SGIP1 | c.236C>A p.P79H | Missense Mutation (SNP) | VAF 67/251 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV52767681; called by muse, mutect2, varscan2
- SGK2 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as rs559824768, COSV58313047; called by muse, mutect2, varscan2
- SLC16A7 | c.54G>C p.W18C | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53894118; called by muse, mutect2, varscan2
- SLC1A3 | c.1609G>T p.D537Y | Missense Mutation (SNP) | VAF 108/266 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV54316198; called by muse, mutect2, varscan2
- SLC22A16 | c.1408C>A p.P470T | Missense Mutation (SNP) | VAF 86/299 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1244482234, COSV57929447, COSV57932211; called by muse, mutect2, varscan2
- SLC22A6 | c.220C>T p.Q74* | Nonsense Mutation (SNP) | VAF 42/138 reads (30%) | catalogued as COSV64560139; called by muse, mutect2, varscan2
- SLC22A7 | c.973G>T p.G325W (on ENST00000372585 / NM_153320.2; = p.G323W on NM_006672.3) | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as COSV51483709, COSV99240067; called by muse, mutect2, varscan2
- SLC25A13 | c.790G>T p.V264F | Missense Mutation (SNP) | VAF 122/421 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.35); catalogued as CM149761, COSV55706613; called by muse, mutect2, varscan2
- SLC27A6 | c.817C>A p.L273M | Missense Mutation (SNP) | VAF 115/323 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.292); catalogued as COSV52482574; called by muse, mutect2, varscan2
- SLC2A3 | c.1267G>T p.A423S | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs201737691, COSV50002302, COSV50003055; called by muse, mutect2, varscan2
- SLC39A6 | c.650A>T p.D217V | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV52369003; called by muse, mutect2, varscan2
- SLC4A10 | c.256G>T p.G86* | Nonsense Mutation (SNP) | VAF 21/121 reads (17%) | catalogued as COSV55776217; called by muse, mutect2, varscan2
- SLC4A8 | c.2246G>C p.G749A | Missense Mutation (SNP) | VAF 163/360 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV60651466; called by muse, mutect2, varscan2
- SLC5A12 | c.1523G>T p.S508I | Missense Mutation (SNP) | VAF 131/350 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV68448731; called by muse, mutect2, varscan2
- SLC8A3 | c.2297G>C p.G766A (on ENST00000381269 / NM_183002.3; = p.G764A on NM_033262.4) | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53689010; called by muse, mutect2, varscan2
- SLC9A8 | c.1690G>T p.E564* | Nonsense Mutation (SNP) | VAF 65/153 reads (42%) | catalogued as COSV64288223; called by muse, mutect2, varscan2
- SLC9C1 | c.3427C>A p.H1143N | Missense Mutation (SNP) | VAF 54/242 reads (22%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.05); catalogued as COSV59887824; called by muse, mutect2, varscan2
- SLCO1B1 | c.1136-2A>C p.X379_splice | Splice Site (SNP) | VAF 16/39 reads (41%) | catalogued as COSV57010642; called by muse, mutect2, varscan2
- SLFN13 | c.2021G>C p.R674P | Missense Mutation (SNP) | VAF 62/311 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53192498, COSV53193305; called by muse, mutect2, varscan2
- SLITRK5 | c.1595G>T p.R532M | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61522587; called by muse, mutect2, varscan2
- SPAG1 | c.2771A>G p.Y924C | Missense Mutation (SNP) | VAF 213/470 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52559582; called by muse, mutect2, varscan2
- SPANXN3 | c.368A>G p.Q123R | Missense Mutation (SNP) | VAF 1397/3551 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.888); catalogued as COSV65140271; called by muse, mutect2, varscan2
- SPATS1 | c.751A>G p.I251V | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV55823072; called by muse, mutect2, varscan2
- SPHKAP | c.682G>T p.D228Y | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs764692127, COSV60877107; called by muse, mutect2, varscan2
- SPTB | c.3163G>T p.D1055Y | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as COSV67631527; called by muse, mutect2, varscan2
- SSU72 | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52216896; called by muse, mutect2
- ST3GAL6 | c.344G>T p.C115F | Missense Mutation (SNP) | VAF 42/199 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54580994; called by muse, mutect2, varscan2
- STK32C | c.613G>T p.D205Y | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53840280; called by muse, mutect2, varscan2
- STRIP1 | c.790A>T p.I264F | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV63929805; called by muse, mutect2, varscan2
- STT3A | c.1460C>G p.S487C | Missense Mutation (SNP) | VAF 134/528 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67064645; called by muse, mutect2, varscan2
- SUCO | c.2114G>T p.S705I | Missense Mutation (SNP) | VAF 215/540 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.046); catalogued as COSV55264633; called by muse, mutect2, varscan2
- SULF2 | c.788G>T p.R263L | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs764984672, COSV63415684; called by muse, mutect2, varscan2
- SUPT7L | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 82/207 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV58134666; called by muse, mutect2, varscan2
- SVEP1 | c.3403G>T p.A1135S | Missense Mutation (SNP) | VAF 117/946 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0.089); catalogued as rs774133551, COSV57035082; called by muse, mutect2, varscan2
- SYNE2 | c.4839G>T p.E1613D | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs751067571, COSV59949210; called by muse, mutect2
- TBC1D23 | c.424C>A p.R142S | Missense Mutation (SNP) | VAF 70/310 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs758687852, COSV61367362, COSV61367665; called by muse, mutect2, varscan2
- TBC1D5 | c.1945C>A p.L649I | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53755506; called by muse, mutect2, varscan2
- TCTEX1D1 | c.532C>A p.L178I | Missense Mutation (SNP) | VAF 68/239 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV51075498, COSV51077255; called by muse, mutect2, varscan2
- TENM2 | c.4312C>T p.L1438F (on ENST00000518659 / NM_001122679.2; = p.L1199F on NM_001080428.3) | Missense Mutation (SNP) | VAF 396/989 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69128786; called by muse, mutect2, varscan2
- TENM4 | c.7634C>T p.S2545F | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); catalogued as COSV53625437; called by muse, mutect2, varscan2
- TENM4 | c.6524G>T p.R2175L | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs745950858, COSV53618292, COSV53625449; called by muse, mutect2, varscan2
- TEX13A | c.23C>G p.P8R | Missense Mutation (SNP) | VAF 52/73 reads (71%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as COSV61155124; called by muse, mutect2, varscan2
- TEX2 | c.3015G>C p.E1005D (on ENST00000583097 / NM_001288733.2; = p.E1012D on NM_018469.5) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV51980535; called by muse, mutect2, varscan2
- TGFBR1 | c.887C>T p.T296I | Missense Mutation (SNP) | VAF 23/283 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.212); catalogued as COSV66625632; called by muse, mutect2
- THBS2 | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 60/191 reads (31%) | catalogued as COSV64678582; called by muse, mutect2, varscan2
- TIGD2 | c.601G>T p.G201W | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV57647680; called by muse, mutect2, varscan2
- TLL1 | c.1042+1G>T p.X348_splice | Splice Site (SNP) | VAF 198/725 reads (27%) | catalogued as COSV50276064; called by muse, mutect2, varscan2
- TMEM132D | c.2064G>T p.R688S | Missense Mutation (SNP) | VAF 137/289 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV67160142, COSV67161670; called by muse, mutect2, varscan2
- TMEM143 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 76/230 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.089); catalogued as rs774864899, COSV53156301, COSV53158109; called by muse, mutect2, varscan2
- TMPRSS11B | c.406C>A p.H136N | Missense Mutation (SNP) | VAF 78/351 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.316); catalogued as COSV60292171; called by muse, mutect2, varscan2
- TNRC6A | c.4273A>G p.R1425G | Missense Mutation (SNP) | VAF 77/303 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV59363708; called by muse, mutect2, varscan2
- TOX2 | c.219C>A p.N73K (on ENST00000358131 / NM_001098798.2; = p.N22K on NM_032883.3) | Missense Mutation (SNP) | VAF 46/349 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs765009016, COSV100363184, COSV57885768; called by muse, mutect2, varscan2
- TPRG1 | c.129G>T p.R43S | Missense Mutation (SNP) | VAF 112/445 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV61463436, COSV61464850; called by muse, mutect2, varscan2
- TRAPPC12 | c.1331C>T p.A444V | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.917); catalogued as COSV60845854; called by muse, mutect2, varscan2
- TRIM29 | c.1291G>T p.D431Y | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV59280088; called by muse, mutect2, varscan2
- TRIML2 | c.601G>T p.G201C | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.525); catalogued as COSV58715889; called by muse, mutect2, varscan2
- TRMT1L | c.1498G>C p.G500R | Missense Mutation (SNP) | VAF 31/352 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV62272239; called by muse, mutect2
- TRO | c.2034G>T p.W678C | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV51500906; called by muse, mutect2, varscan2
- TRPA1 | c.1241G>C p.C414S | Missense Mutation (SNP) | VAF 36/209 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51560529; called by muse, mutect2, varscan2
- TRPM3 | c.1586C>A p.T529K (on ENST00000357533 / NM_001366142.2; = p.T374K on NM_020952.6) | Missense Mutation (SNP) | VAF 47/262 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV62585062; called by muse, mutect2, varscan2
- TRPM6 | c.3537-2A>G p.X1179_splice | Splice Site (SNP) | VAF 70/193 reads (36%) | catalogued as COSV62508881; called by muse, mutect2, varscan2
- TRPM6 | c.1498-1G>T p.X500_splice | Splice Site (SNP) | VAF 65/213 reads (31%) | catalogued as COSV62508891; called by muse, mutect2, varscan2
- TRPV4 | c.1446G>T p.M482I | Missense Mutation (SNP) | VAF 73/125 reads (58%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); catalogued as COSV55681949; called by muse, mutect2, varscan2
- TTC17 | c.262G>T p.A88S | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.13); catalogued as COSV50008209; called by muse, mutect2, varscan2
- TTN | c.78095C>T p.P26032L (on ENST00000591111; = p.P18608L on NM_003319.4) | Missense Mutation (SNP) | VAF 124/484 reads (26%) | PolyPhen probably damaging (0.999); catalogued as COSV100600568, COSV60021663; called by muse, mutect2, varscan2
- TTN | c.72155T>G p.I24052S (on ENST00000591111; = p.I16628S on NM_003319.4) | Missense Mutation (SNP) | VAF 80/279 reads (29%) | PolyPhen benign (0.122); catalogued as COSV60021709; called by muse, mutect2, varscan2
- TTN | c.58456C>G p.R19486G (on ENST00000591111; = p.R12062G on NM_003319.4) | Missense Mutation (SNP) | VAF 14/99 reads (14%) | PolyPhen benign (0.077); catalogued as COSV60021757; called by muse, mutect2, varscan2
- TTN | c.29654C>A p.P9885H (on ENST00000591111; = p.P8958H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/313 reads (28%) | PolyPhen probably damaging (0.997); catalogued as COSV60021807, COSV60260624; called by muse, mutect2, varscan2
- TTN | c.29314G>T p.V9772L (on ENST00000591111; = p.V8845L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 100/317 reads (32%) | PolyPhen probably damaging (0.99); catalogued as COSV60021821; called by muse, mutect2, varscan2
- TXLNB | c.764C>A p.T255K | Missense Mutation (SNP) | VAF 67/238 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as rs754093195, COSV62727310, COSV62727544; called by muse, mutect2, varscan2
- U2SURP | c.1585A>T p.S529C | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV67530727; called by muse, mutect2, varscan2
- UGT2B4 | c.1561A>G p.T521A | Missense Mutation (SNP) | VAF 68/251 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV59316866; called by muse, mutect2, varscan2
- URGCP | c.584A>T p.D195V (on ENST00000453200 / NM_001077663.3; = p.D186V on NM_017920.4) | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV56247160; called by muse, mutect2, varscan2
- UROC1 | c.721G>A p.G241R | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52032542, COSV99330993; called by muse, mutect2, varscan2
- USO1 | c.1247G>T p.G416V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs775864291, COSV53706486; called by muse, mutect2, varscan2
- UTRN | c.6195G>T p.W2065C | Missense Mutation (SNP) | VAF 83/424 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62334220; called by muse, mutect2, varscan2
- VAX1 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV53328786, COSV99524486; called by muse, mutect2, varscan2
- VPS13B | c.7723G>T p.G2575W | Missense Mutation (SNP) | VAF 68/292 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV62132589, COSV62144879; called by muse, mutect2, varscan2
- VPS13C | c.883+1G>T p.X295_splice (on ENST00000644861 / NM_020821.3; = p.X252_splice on NM_017684.5) | Splice Site (SNP) | VAF 18/50 reads (36%) | catalogued as COSV51166399; called by muse, varscan2
- VPS36 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 15/17 reads (88%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.884); catalogued as COSV51621831; called by muse, varscan2
- WDR17 | c.1960G>T p.D654Y | Missense Mutation (SNP) | VAF 52/224 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54572856; called by muse, mutect2, varscan2
- WDR70 | c.1407C>G p.I469M | Missense Mutation (SNP) | VAF 34/249 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV54271776; called by muse, mutect2, varscan2
- WNT1 | c.371C>A p.T124K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53295750; called by muse, varscan2
- ZAN | c.6064C>A p.Q2022K | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as COSV100769274; called by muse, mutect2, varscan2
- ZBBX | c.1322G>T p.G441V | Missense Mutation (SNP) | VAF 68/257 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV56788305; called by muse, mutect2, varscan2
- ZC3HAV1 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 43/193 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV54295389; called by muse, mutect2, varscan2
- ZFAND2B | c.565G>A p.V189M | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.428); catalogued as rs757405010, COSV54695586; called by muse, varscan2
- ZFC3H1 | c.2600A>G p.K867R | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV66432170; called by muse, mutect2, varscan2
- ZFHX4 | c.4676A>T p.H1559L | Missense Mutation (SNP) | VAF 78/280 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50732186; called by muse, mutect2, varscan2
- ZFP42 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV58817268, COSV58818552; called by muse, mutect2, varscan2
- ZIM3 | c.1075G>A p.G359R | Missense Mutation (SNP) | VAF 90/232 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54142259; called by muse, mutect2, varscan2
- ZMAT1 | c.411G>T p.Q137H | Missense Mutation (SNP) | VAF 552/803 reads (69%) | SIFT tolerated (0.35); PolyPhen benign (0.041); catalogued as COSV65658377; called by muse, mutect2, varscan2
- ZMAT1 | c.299A>T p.K100M | Missense Mutation (SNP) | VAF 135/337 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV65658383; called by muse, mutect2, varscan2
- ZNF208 | c.2858C>A p.A953D | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV68104509; called by muse, mutect2
- ZNF354A | c.1489A>T p.N497Y | Missense Mutation (SNP) | VAF 67/166 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59983073; called by muse, mutect2, varscan2
- ZNF521 | c.136G>T p.V46L | Missense Mutation (SNP) | VAF 141/406 reads (35%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as COSV64122545, COSV64126322; called by muse, mutect2, varscan2
- ZNF570 | c.1594A>T p.N532Y | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.265); catalogued as COSV57578905; called by muse, mutect2, varscan2
- ZNF783 | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV65185330, COSV65186376; called by muse, mutect2, varscan2
- ZNF804A | c.3563C>A p.P1188H | Missense Mutation (SNP) | VAF 117/750 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV56446699; called by muse, mutect2, varscan2
- ZNF804B | c.3397G>T p.E1133* | Nonsense Mutation (SNP) | VAF 70/251 reads (28%) | catalogued as COSV60825794; called by muse, mutect2, varscan2
- ZP4 | c.195C>A p.H65Q | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.877); catalogued as rs527859514, COSV63911812; called by muse, mutect2, varscan2
- ACTN3 | c.515C>A p.T172K | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ALKBH8 | c.411_416del p.M138_V139del | In Frame Del (DEL) | VAF 20/101 reads (20%) | called by mutect2, pindel, varscan2
- CEL | c.298del p.D100Mfs*25 (on ENST00000673714; = p.D97Mfs*25 on NM_001807.6) | Frame Shift Del (DEL) | VAF 11/42 reads (26%) | called by mutect2, pindel, varscan2
- LRRC4C | c.823del p.A275Hfs*5 | Frame Shift Del (DEL) | VAF 205/655 reads (31%) | called by mutect2, pindel, varscan2
- LYZL6 | c.365G>T p.G122V | Missense Mutation (SNP) | VAF 62/281 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR56A4 | c.449del p.P150Qfs*10 | Frame Shift Del (DEL) | VAF 53/202 reads (26%) | called by mutect2, pindel, varscan2
- PTPRA | c.118del p.A40Qfs*17 | Frame Shift Del (DEL) | VAF 82/235 reads (35%) | called by mutect2, pindel, varscan2
- SPATA17 | c.793del p.A265Qfs*7 | Frame Shift Del (DEL) | VAF 96/273 reads (35%) | called by mutect2, pindel, varscan2
- TP53 | c.686_687del p.C229Yfs*10 | Frame Shift Del (DEL) | VAF 85/277 reads (31%) | called by mutect2, pindel, varscan2
- TRAV8-6 | c.85C>T p.Q29* | Nonsense Mutation (SNP) | VAF 269/926 reads (29%) | called by muse, mutect2, varscan2
- TRGC1 | c.29C>A p.P10H | Missense Mutation (SNP) | VAF 79/498 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDR25 | c.970+2dup p.X324_splice | Splice Site (INS) | VAF 24/120 reads (20%) | called by mutect2, varscan2
- ZNF746 | c.120dup p.M41Dfs*8 | Frame Shift Ins (INS) | VAF 44/171 reads (26%) | called by mutect2, varscan2
- ABCC11 | c.3234C>A p.V1078= | Silent (SNP) | VAF 159/423 reads (38%) | catalogued as COSV62322829; called by muse, mutect2, varscan2
- ACADL | c.183G>C p.R61= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV52053223; called by muse, mutect2, varscan2
- ACTA1 | c.414C>A p.I138= | Silent (SNP) | VAF 46/141 reads (33%) | catalogued as CM012323, COSV64202855, COSV64203258; called by muse, mutect2, varscan2
- ADAMTS5 | c.2580C>T p.N860= | Silent (SNP) | VAF 64/242 reads (26%) | catalogued as COSV53178635; called by muse, mutect2, varscan2
- AHCY | c.741C>T p.I247= | Silent (SNP) | VAF 69/222 reads (31%) | catalogued as COSV54153129; called by muse, mutect2, varscan2
- ALDH2 | c.1128G>T p.T376= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV55666882; called by muse, mutect2, varscan2
- AMER2 | c.1284G>T p.P428= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV63437234, COSV63438005; called by muse, mutect2, varscan2
- ANKS4B | c.315T>A p.A105= | Silent (SNP) | VAF 51/208 reads (25%) | catalogued as COSV61139118; called by muse, varscan2
- AP3D1 | c.828C>T p.L276= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV61427644; called by muse, mutect2, varscan2
- ATP2A1 | c.1311C>A p.V437= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV63920821, COSV63922741; called by muse, mutect2, varscan2
- AZIN2 | c.873C>T p.I291= | Silent (SNP) | VAF 151/615 reads (25%) | catalogued as COSV53857172; called by muse, mutect2, varscan2
- BCAN | c.858C>G p.T286= | Silent (SNP) | VAF 113/288 reads (39%) | catalogued as COSV61256681; called by muse, mutect2, varscan2
- C1orf56 | c.651C>A p.T217= | Silent (SNP) | VAF 25/102 reads (25%) | catalogued as COSV54846090, COSV54846859; called by muse, mutect2, varscan2
- CACNA2D4 | c.1917G>C p.T639= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV54949465, COSV99765881; called by muse, mutect2, varscan2
- CAPN13 | c.1905G>T p.L635= | Silent (SNP) | VAF 32/89 reads (36%) | catalogued as COSV54430159, COSV54432250; called by muse, mutect2, varscan2
- CD163L1 | c.1026A>G p.R342= | Silent (SNP) | VAF 51/189 reads (27%) | catalogued as rs376908493; called by muse, mutect2, varscan2
- CDC42BPA | c.3625A>C p.R1209= (on ENST00000334218 / NM_001366019.2; = p.R1196= on NM_003607.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 203/508 reads (40%) | catalogued as COSV62010105; called by muse, mutect2, varscan2
- CDC42BPG | c.1056T>C p.Y352= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV61347094; called by muse, mutect2, varscan2
- CDH9 | c.294C>T p.G98= | Silent (SNP) | VAF 89/286 reads (31%) | catalogued as rs746000961, COSV50276625, COSV99141286; called by muse, mutect2, varscan2
- CEP63 | c.1848T>C p.S616= | Silent (SNP) | VAF 178/602 reads (30%) | catalogued as COSV59676048; called by muse, mutect2, varscan2
- CFAP94 | c.2148C>A p.S716= (on ENST00000320267 / NM_001352064.2; = p.S722= on NM_018272.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/101 reads (31%) | catalogued as COSV57231917; called by muse, mutect2, varscan2
- CNTN5 | c.1260G>T p.T420= | Silent (SNP) | VAF 31/138 reads (22%) | catalogued as COSV54307004; called by muse, mutect2, varscan2
- CNTN5 | c.1566T>C p.V522= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV54307018; called by mutect2, varscan2
- CNTNAP5 | c.1389G>T p.T463= | Silent (SNP) | VAF 146/380 reads (38%) | catalogued as COSV70484151; called by muse, mutect2, varscan2
- COL14A1 | c.1236G>A p.L412= | Silent (SNP) | VAF 44/118 reads (37%) | catalogued as rs558868115, COSV52853315; called by muse, mutect2, varscan2
- CORIN | c.921C>T p.S307= | Silent (SNP) | VAF 42/182 reads (23%) | catalogued as rs1197392756, COSV56690677; called by muse, mutect2, varscan2
- CPXM2 | c.1179G>T p.V393= | Silent (SNP) | VAF 203/514 reads (39%) | catalogued as COSV53861107; called by muse, mutect2, varscan2
- CSMD3 | c.5115C>A p.G1705= (on ENST00000297405 / NM_001363185.1; = p.G1601= on NM_052900.3) | Silent (SNP) | VAF 181/489 reads (37%) | catalogued as COSV52167279, COSV99835799; called by muse, mutect2, varscan2
- DAW1 | c.921A>T p.L307= | Silent (SNP) | VAF 58/459 reads (13%) | catalogued as COSV59365103; called by muse, mutect2, varscan2
- DDX53 | c.354C>T p.S118= | Silent (SNP) | VAF 47/102 reads (46%) | catalogued as COSV60068949; called by muse, mutect2, varscan2
- DNAH10 | c.8361G>A p.R2787= (on ENST00000409039; = p.R2726= on NM_207437.3) | Silent (SNP) | VAF 568/1212 reads (47%) | catalogued as rs1566036797, COSV68992714, COSV69005785; called by muse, mutect2, varscan2
- DNAH8 | c.2124A>G p.L708= | Silent (SNP) | VAF 59/122 reads (48%) | catalogued as COSV59442267; called by muse, mutect2, varscan2
- DST | c.6636C>T p.N2212= | Silent (SNP) | VAF 37/126 reads (29%) | catalogued as COSV99754580; called by muse, mutect2, varscan2
- DTX1 | c.277C>A p.R93= | Silent (SNP) | VAF 32/65 reads (49%) | catalogued as COSV57497140; called by muse, mutect2, varscan2
- DYNC2H1 | c.10483C>T p.L3495= | Silent (SNP) | VAF 45/212 reads (21%) | catalogued as COSV62093048; called by muse, mutect2, varscan2
- ESYT2 | c.2415G>C p.V805= (on ENST00000613624; = p.V729= on NM_020728.3) | Silent (SNP) | VAF 42/205 reads (20%) | catalogued as COSV51750527; called by muse, mutect2, varscan2
- FAM13A | c.855C>T p.S285= | Silent (SNP) | VAF 68/285 reads (24%) | catalogued as COSV52001813; called by muse, mutect2, varscan2
- FAM149A | c.1335G>T p.P445= (on ENST00000356371 / NM_001367768.2; = p.P154= on NM_015398.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 32/139 reads (23%) | catalogued as COSV57027124; called by muse, mutect2, varscan2
- FARP2 | c.1731G>T p.T577= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV50870896, COSV99884336; called by muse, mutect2, varscan2
- FAT3 | c.12945G>A p.G4315= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV53104956; called by muse, mutect2, varscan2
- FER1L6 | c.4701C>T p.R1567= | Silent (SNP) | VAF 162/321 reads (50%) | catalogued as COSV67549662; called by muse, mutect2, varscan2
- FGF14 | c.576A>C p.P192= | Silent (SNP) | VAF 40/144 reads (28%) | catalogued as COSV65942495; called by muse, mutect2, varscan2
- FMNL3 | c.1482G>C p.L494= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as COSV53301308; called by muse, mutect2, varscan2
- FRMPD1 | c.2637A>C p.A879= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV66700209; called by muse, mutect2
- FRYL | c.1872T>A p.R624= | Silent (SNP) | VAF 28/158 reads (18%) | catalogued as COSV51945962; called by muse, mutect2, varscan2
- GBP1 | c.723C>T p.P241= | Silent (SNP) | VAF 83/323 reads (26%) | catalogued as rs750533336, COSV65083368; called by muse, mutect2, varscan2
- GHSR | c.1026C>A p.P342= | Silent (SNP) | VAF 32/121 reads (26%) | catalogued as COSV53838768, COSV53840426; called by muse, mutect2, varscan2
- GLYATL2 | c.414A>G p.P138= | Silent (SNP) | VAF 98/365 reads (27%) | catalogued as COSV54849815; called by muse, mutect2, varscan2
- GLYATL2 | c.87C>A p.G29= | Silent (SNP) | VAF 26/117 reads (22%) | catalogued as COSV54849206, COSV54849827; called by muse, mutect2, varscan2
- GPR83 | c.180C>G p.R60= | Silent (SNP) | VAF 41/163 reads (25%) | catalogued as COSV54718524; called by muse, mutect2, varscan2
- GPRC6A | c.807C>G p.A269= | Silent (SNP) | VAF 75/214 reads (35%) | catalogued as COSV59952820; called by muse, mutect2, varscan2
- HECW1 | c.594A>G p.G198= | Silent (SNP) | VAF 38/295 reads (13%) | catalogued as COSV67828348; called by muse, mutect2, varscan2
- HMCN1 | c.3366G>A p.P1122= | Silent (SNP) | VAF 58/175 reads (33%) | catalogued as rs199798509; called by muse, mutect2, varscan2
- HS3ST3B1 | c.645G>T p.S215= | Silent (SNP) | VAF 37/87 reads (43%) | catalogued as COSV62906470; called by muse, mutect2, varscan2
- IGHD | c.123C>T p.T41= | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as rs1332545903, COSV66655078; called by muse, mutect2, varscan2
- IL16 | c.1566G>T p.G522= | Silent (SNP) | VAF 51/127 reads (40%) | catalogued as COSV57263033; called by muse, mutect2, varscan2
- ITGA4 | c.213G>A p.A71= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV51999811; called by muse, mutect2, varscan2
- ITGAM | c.1587G>T p.G529= (on ENST00000648685 / NM_001145808.2; = p.G528= on NM_000632.4) | Silent (SNP) | VAF 174/777 reads (22%) | catalogued as COSV54936670; called by muse, mutect2, varscan2
- ITPKB | c.2706G>T p.T902= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV55261119; called by muse, mutect2, varscan2
- JKAMP | c.945A>T p.S315= (on ENST00000554271 / NM_001284201.1; = p.S301= on NM_016475.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 59/212 reads (28%) | catalogued as COSV54199285; called by muse, mutect2, varscan2
- KCNQ2 | c.1683C>G p.P561= (on ENST00000359125 / NM_172107.4; = p.P533= on NM_004518.6) | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV60544005; called by muse, mutect2, varscan2
- KCTD14 | c.687C>T p.F229= | Silent (SNP) | VAF 47/225 reads (21%) | catalogued as COSV62001377; called by muse, mutect2, varscan2
- KIF2B | c.960G>T p.T320= | Silent (SNP) | VAF 78/276 reads (28%) | catalogued as COSV52129902; called by muse, mutect2
- KRTAP13-1 | c.105C>T p.V35= | Silent (SNP) | VAF 86/363 reads (24%) | catalogued as COSV62663269; called by muse, varscan2
- LCE1E | c.66C>T p.P22= | Silent (SNP) | VAF 64/238 reads (27%) | catalogued as COSV64219761; called by muse, mutect2, varscan2
- MAGEB3 | c.864C>T p.V288= | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as COSV64397033; called by muse, mutect2, varscan2
- MANSC1 | c.282C>T p.N94= | Silent (SNP) | VAF 59/182 reads (32%) | catalogued as COSV67110974; called by muse, mutect2, varscan2
- MAP3K14 | c.822C>T p.P274= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs774026847, COSV60923482; called by muse, mutect2
- MARCHF1 | c.444C>A p.T148= (on ENST00000274056; = p.T131= on NM_017923.4) | Silent (SNP) | VAF 136/551 reads (25%) | catalogued as COSV56813927; called by muse, mutect2, varscan2
- MARCO | c.360C>A p.L120= | Silent (SNP) | VAF 49/284 reads (17%) | catalogued as COSV59053966; called by muse, mutect2, varscan2
- MEGF10 | c.2298C>T p.D766= | Silent (SNP) | VAF 98/252 reads (39%) | catalogued as COSV57248556; called by muse, mutect2, varscan2
- MS4A4A | c.207G>T p.V69= | Silent (SNP) | VAF 107/513 reads (21%) | catalogued as COSV59701080; called by muse, mutect2, varscan2
- MUC17 | c.3864G>T p.T1288= | Silent (SNP) | VAF 179/875 reads (20%) | catalogued as COSV100075349, COSV60287268; called by muse, mutect2, varscan2
- MYH6 | c.1950G>T p.S650= | Silent (SNP) | VAF 41/126 reads (33%) | catalogued as COSV62449955; called by muse, mutect2, varscan2
- MYH7 | c.4242G>T p.L1414= | Silent (SNP) | VAF 34/117 reads (29%) | catalogued as COSV100806001; called by muse, mutect2, varscan2
- NAA11 | c.261C>A p.A87= | Silent (SNP) | VAF 36/129 reads (28%) | catalogued as rs1376891189, COSV54514454; called by muse, mutect2, varscan2
- NID1 | c.1668G>T p.V556= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV51619344; called by muse, mutect2
- NOD2 | c.912C>A p.G304= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV56050334; called by muse, mutect2, varscan2
- NPAP1 | c.1533C>A p.V511= | Silent (SNP) | VAF 102/254 reads (40%) | catalogued as COSV100275799, COSV61506441; called by muse, mutect2, varscan2
- NUP210L | c.4278G>A p.Q1426= | Silent (SNP) | VAF 41/189 reads (22%) | catalogued as COSV55146825; called by muse, mutect2, varscan2
- OLFML1 | c.1146C>A p.A382= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs750947115, COSV55076675; called by muse, mutect2, varscan2
- OR10AG1 | c.642C>T p.S214= | Silent (SNP) | VAF 22/102 reads (22%) | catalogued as rs894204896, COSV56632705; called by muse, mutect2, varscan2
- OR13C8 | c.612G>T p.L204= | Silent (SNP) | VAF 85/384 reads (22%) | catalogued as COSV58611020, COSV58611922; called by muse, mutect2, varscan2
- OR13G1 | c.834G>T p.V278= | Silent (SNP) | VAF 121/366 reads (33%) | catalogued as COSV62943280, COSV62944042; called by muse, mutect2, varscan2
- OR2K2 | c.514C>A p.R172= (on ENST00000374428; = p.R143= on NM_205859.2) | Silent (SNP) | VAF 405/761 reads (53%) | catalogued as COSV57016802; called by muse, mutect2, varscan2
- OR4D5 | c.901C>T p.L301= | Silent (SNP) | VAF 169/582 reads (29%) | catalogued as COSV58306693; called by muse, mutect2, varscan2
- OR5M1 | c.108A>T p.L36= | Silent (SNP) | VAF 161/630 reads (26%) | catalogued as COSV73202102; called by muse, mutect2, varscan2
- OR6S1 | c.879T>C p.Y293= | Silent (SNP) | VAF 193/705 reads (27%) | catalogued as COSV57838039; called by muse, mutect2, varscan2
- OR8D4 | c.21C>T p.S7= | Silent (SNP) | VAF 49/186 reads (26%) | catalogued as rs207472447, COSV58430239; called by muse, mutect2, varscan2
- OR9G4 | c.21C>A p.T7= | Silent (SNP) | VAF 147/535 reads (27%) | catalogued as COSV57248413; called by muse, mutect2, varscan2
- PAPPA2 | c.4464C>T p.R1488= | Silent (SNP) | VAF 82/900 reads (9%) | catalogued as COSV62796618; called by muse, mutect2
- PDE3A | c.2676G>T p.V892= | Silent (SNP) | VAF 51/155 reads (33%) | catalogued as COSV100762044; called by muse, mutect2, varscan2
- PER2 | c.1935G>T p.T645= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV54523281, COSV54523397; called by muse, mutect2, varscan2
- PIK3CG | c.2163G>T p.L721= | Silent (SNP) | VAF 44/157 reads (28%) | catalogued as COSV63247978; called by muse, mutect2, varscan2
- PPIAL4A | c.336T>C p.F112= | Silent (SNP) | VAF 120/321 reads (37%) | called by muse, varscan2
- PROKR2 | c.387C>A p.A129= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV54086338; called by muse, mutect2, varscan2
- PTPN13 | c.5928T>G p.S1976= (on ENST00000411767 / NM_080683.3; = p.S1957= on NM_006264.3) | Silent (SNP) | VAF 40/146 reads (27%) | catalogued as COSV57406583; called by muse, mutect2, varscan2
- RLF | c.5568C>T p.S1856= | Silent (SNP) | VAF 58/209 reads (28%) | catalogued as rs759354966, COSV65650969, COSV65651644; called by muse, mutect2, varscan2
- RNF26 | c.1254C>T p.C418= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV60990366; called by muse, mutect2, varscan2
- RTP2 | c.522G>A p.E174= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as COSV64078970; called by muse, mutect2, varscan2
- RUNX1T1 | c.819C>A p.G273= (on ENST00000265814 / NM_001198628.1; = p.G246= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 63/184 reads (34%) | catalogued as rs756137201, COSV56145186; called by muse, mutect2, varscan2
- S1PR1 | c.177C>A p.I59= | Silent (SNP) | VAF 77/389 reads (20%) | catalogued as COSV59513137; called by muse, mutect2, varscan2
- SDE2 | c.669A>C p.A223= | Silent (SNP) | VAF 62/200 reads (31%) | catalogued as COSV55251099; called by muse, mutect2, varscan2
- SEC23A | c.621T>G p.S207= | Silent (SNP) | VAF 33/120 reads (28%) | catalogued as COSV56973510; called by muse, mutect2, varscan2
- SEMA5B | c.2598C>A p.S866= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV52096696, COSV52097289; called by muse, mutect2, varscan2
- SH2D2A | c.304C>A p.R102= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as COSV63884744; called by muse, mutect2, varscan2
- SLC12A3 | c.420G>A p.K140= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV52634575; called by muse, mutect2
- SLC16A1 | c.1314C>T p.F438= | Silent (SNP) | VAF 60/202 reads (30%) | catalogued as COSV63709201; called by muse, mutect2, varscan2
- SLC30A8 | c.606C>A p.G202= | Silent (SNP) | VAF 65/341 reads (19%) | catalogued as COSV69970180; called by muse, mutect2, varscan2
- SLC44A5 | c.2058G>T p.L686= | Silent (SNP) | VAF 44/189 reads (23%) | catalogued as COSV63763794; called by muse, mutect2, varscan2
- SLC47A1 | c.183G>T p.V61= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV54500854; called by muse, mutect2, varscan2
- SLIT3 | c.4197G>T p.G1399= | Silent (SNP) | VAF 54/144 reads (38%) | catalogued as COSV60606141; called by muse, mutect2, varscan2
- SORCS3 | c.2211A>G p.S737= | Silent (SNP) | VAF 97/278 reads (35%) | catalogued as COSV63794779; called by muse, mutect2, varscan2
- SPPL2C | c.21C>T p.L7= | Silent (SNP) | VAF 24/106 reads (23%) | catalogued as COSV61292019; called by muse, mutect2, varscan2
- SPTA1 | c.1185T>A p.A395= | Silent (SNP) | VAF 372/1007 reads (37%) | catalogued as COSV100935469, COSV63752385; called by muse, mutect2, varscan2
- SYT12 | c.891C>A p.A297= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV67353918; called by muse, mutect2, varscan2
- TAS2R60 | c.711C>G p.P237= | Silent (SNP) | VAF 94/336 reads (28%) | catalogued as COSV100223484, COSV60330743; called by muse, mutect2, varscan2
- TAT | c.786A>T p.P262= | Silent (SNP) | VAF 26/146 reads (18%) | catalogued as COSV63532754; called by muse, mutect2, varscan2
- THOC2 | c.3951C>T p.T1317= | Silent (SNP) | VAF 321/561 reads (57%) | catalogued as COSV55545112; called by muse, mutect2, varscan2
- TICRR | c.1806G>T p.V602= | Silent (SNP) | VAF 83/236 reads (35%) | catalogued as COSV51540991; called by muse, mutect2, varscan2
- TIE1 | c.2349G>T p.L783= | Silent (SNP) | VAF 29/134 reads (22%) | catalogued as COSV65249539; called by muse, mutect2, varscan2
- TIGD4 | c.63A>G p.L21= | Silent (SNP) | VAF 60/183 reads (33%) | catalogued as rs377316836; called by muse, mutect2, varscan2
- TINAG | c.948C>A p.T316= | Silent (SNP) | VAF 212/728 reads (29%) | catalogued as COSV52509004; called by muse, mutect2, varscan2
- TMEM132E | c.1671G>T p.T557= (on ENST00000321639; = p.T647= on NM_001304438.2) | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as rs146893987, COSV58696615; called by muse, mutect2, varscan2
- TMEM150C | c.291G>A p.P97= | Silent (SNP) | VAF 43/179 reads (24%) | catalogued as rs778294608, COSV71388959; called by muse, mutect2, varscan2
- TNNI3K | c.1860C>T p.N620= | Silent (SNP) | VAF 23/117 reads (20%) | catalogued as COSV58552949; called by muse, mutect2, varscan2
- TRADD | c.99G>T p.A33= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV50757747, COSV50758005; called by muse, mutect2, varscan2
- TRAK1 | c.96G>T p.V32= | Silent (SNP) | VAF 35/112 reads (31%) | catalogued as COSV59641910; called by muse, mutect2, varscan2
- UNC13C | c.3834C>A p.S1278= | Silent (SNP) | VAF 41/111 reads (37%) | catalogued as COSV52868155, COSV99520117; called by muse, mutect2, varscan2
- ZAN | c.6063C>A p.S2021= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV100769604; called by muse, mutect2, varscan2
- ZEB2 | c.21G>T p.A7= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV57956184; called by muse, mutect2
- ZNF423 | c.3654G>T p.P1218= (on ENST00000563137 / NM_001379286.1; = p.P1210= on NM_015069.4) | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as COSV52186601; called by muse, mutect2, varscan2
- ZPBP | c.249G>T p.V83= | Silent (SNP) | VAF 77/309 reads (25%) | catalogued as COSV50424691; called by muse, mutect2, varscan2
- ZXDC | c.1803G>T p.V601= | Silent (SNP) | VAF 37/152 reads (24%) | catalogued as rs367640578; called by muse, mutect2, varscan2
- FCRL2 | c.884-120G>A | Intron (SNP) | VAF 110/585 reads (19%) | catalogued as rs762127162, COSV100829889; called by muse, mutect2, varscan2
- HERC2P3 | chr15:20457720 C>T | 5'Flank (SNP) | VAF 51/306 reads (17%) | called by muse, mutect2, varscan2
- HNF4G | c.-23-3772C>A | Intron (SNP) | VAF 75/377 reads (20%) | catalogued as rs766570244, COSV100584355; called by muse, mutect2, varscan2
- MIR409 | n.74G>A | RNA (SNP) | VAF 22/77 reads (29%) | catalogued as rs781392080; called by muse, mutect2, varscan2
- RN7SL484P | chr15:99792080 C>A | 3'Flank (SNP) | VAF 7/35 reads (20%) | called by muse, mutect2
- RUNDC3A | c.1199-599C>G | Intron (SNP) | VAF 7/46 reads (15%) | catalogued as COSV99835200; called by muse, mutect2, varscan2
- SLC2A9 | chr4:10025939 C>A | 5'Flank (SNP) | VAF 32/125 reads (26%) | catalogued as COSV53319948; called by muse, mutect2, varscan2
- SNORD115-42 | n.9G>T | RNA (SNP) | VAF 42/151 reads (28%) | called by muse, mutect2, varscan2
- TEX29 | chr13:111316247 G>T | 5'Flank (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2, varscan2
- TRIM61 | c.526-2103C>A | Intron (SNP) | VAF 10/55 reads (18%) | catalogued as COSV61418037; called by muse, mutect2, varscan2
